Somatic mutation profile of tumor specimen TCGA-DH-A66G-01A (aliquot TCGA-DH-A66G-01A-21D-A31L-08) from TCGA case TCGA-DH-A66G, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 49.8 years (18,199 days).
Specimen TCGA-DH-A66G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d2c67bb-6d99-4eaf-a6c7-0d425a311c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A66G-10A (Blood Derived Normal), aliquot TCGA-DH-A66G-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc063a1e-5e71-4c93-96fa-5039fd4f6a8a

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Splice Site 3, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 49/77 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs543249891, COSV52943095; called by muse, mutect2, varscan2
- COL19A1 | c.2241A>G p.G747= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100506039; called by muse, varscan2
- CSHL1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.436); catalogued as COSV99367928; called by muse, mutect2, varscan2
- DOCK5 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV99376680, COSV99377800; called by muse, mutect2, varscan2
- FLVCR1 | c.533T>A p.L178Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100757900; called by muse, mutect2, varscan2
- KIF5A | c.589+2T>C p.X197_splice | Splice Site (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99672840; called by muse, mutect2, varscan2
- LRRC55 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101546729; called by muse, mutect2, varscan2
- OR52N1 | c.188T>A p.V63D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100398642; called by muse, mutect2, varscan2
- PDILT | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 189/521 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV100199291; called by muse, mutect2, varscan2
- RERE | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100555878; called by muse, mutect2
- SLCO6A1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV65808387, COSV65808697; called by muse, mutect2, varscan2
- SLITRK2 | c.1882G>T p.V628F | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100157624, COSV59425002; called by muse, mutect2
- TENT4A | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100048812; called by muse, mutect2, varscan2
- TRIM41 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100163134; called by muse, mutect2
- USP26 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100896604; called by muse, mutect2, varscan2
- WDR92 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99718254; called by muse, mutect2
- ATRX | c.5270_5272+1del p.X1757_splice | Splice Site (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- CDH16 | c.2275+2del p.X759_splice | Splice Site (DEL) | VAF 44/201 reads (22%) | called by mutect2, pindel, varscan2
- ZFX | c.1596del p.L533Yfs*2 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- IFNA14 | c.387G>A p.V129= | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as COSV66516353; called by muse, mutect2, varscan2
- NCKAP1L | c.2616G>T p.V872= | Silent (SNP) | VAF 55/151 reads (36%) | catalogued as COSV99514892; called by muse, mutect2, varscan2
- OR2T35 | c.756C>T p.Y252= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs747627097, COSV100442116; called by muse, mutect2, varscan2
- PDE3A | c.2703C>T p.V901= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100762041; called by muse, mutect2, varscan2
- PLA2G15 | c.321T>C p.F107= | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as rs1277686740, COSV99547174; called by muse, mutect2
- SLC12A3 | c.1383C>A p.I461= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99344073; called by muse, mutect2, varscan2
- ZNF827 | c.522C>T p.A174= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs773501716, COSV65232750; called by muse, mutect2, varscan2
- AC024940.1 | n.3207A>G | RNA (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
